Somatic mutation profile of tumor specimen TARGET-30-PAKIPY-01A (aliquot TARGET-30-PAKIPY-01A-01W) from TARGET case TARGET-30-PAKIPY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,116 days).
Specimen TARGET-30-PAKIPY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6f71094-3173-40cc-a14e-d5e60723e03b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKIPY-10A (Blood Derived Normal), aliquot TARGET-30-PAKIPY-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d66fcb1-ce87-492c-9b1b-7b8ff41beef5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9L | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV99420460; called by muse, mutect2
- MS4A7 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100279339, COSV55731903; called by muse, mutect2
- TBX21 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99456040; called by muse, mutect2
- CCDC70 | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- CCKAR | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 18/355 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSGALNACT1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 30/850 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- H4C2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- KLF3 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2
- PRPF8 | c.1176C>A p.P392= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
